Gene-level copy-number profile of tumor specimen TCGA-HU-A4GC-01A from TCGA case TCGA-HU-A4GC, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.7 years (27,267 days).
Specimen TCGA-HU-A4GC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c447875e-537b-4f54-bf64-d1b0e63c1f11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f0489989-93b4-480d-8fde-b3d31f008b7d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 6,643; copy number 2: 23,512; copy number 3: 14,169; copy number 4: 11,253; copy number 5: 1,728; copy number 6: 1,959; copy number 7: 388; copy number 9: 86; copy number 11: 9; copy number 12: 14; copy number 14: 2; copy number 20: 1; copy number 29: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GC-01A-12D-A253-01): tumor purity 0.33, ploidy 2.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,231 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:65,034,634–66,897,371, 17 genes, copy number 5: AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr4:104,653,874–113,384,221, 143 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:133,149,294–135,913,680, 21 genes, copy number 6 (within-gene range 3–6): PCDH10, AC108052.1, AC105252.1, AC079380.1, AC015631.1, AC096763.1, PABPC4L, PES1P1, LINC02462, AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, U6, KRT18P54, TARS2P1, AC105362.1, LINC00613.
- chr4:187,201,986–190,092,279, 59 genes, copy number 5: LINC02374, AC097652.1, LINC02514, LINC02515, AC093763.2, AC093763.1, LINC02492, AC097521.1, ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:58,198–18,746,173, 345 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:20,002,765–20,003,247, 1 gene, copy number 20: RPL21P75.
- chr7:49,230,137–68,724,048, 420 genes, copy number 5 (broad region; genes not listed).
- chr7:98,794,718–103,989,658, 218 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–9,425,524, 229 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:10,606,349–15,967,950, 139 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:42,896,946–145,066,685, 1,564 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr11:68,683,779–71,670,297, 84 genes, copy number 9 (broad region; genes not listed).
- chr11:71,690,453–71,705,404, 2 genes, copy number 9: SNRPCP14, AP003498.1.
- chr11:77,322,017–79,441,030, 42 genes, copy number 7 (within-gene range 2–7): PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1.
- chr12:752,579–911,452, 1 gene, copy number 6 (within-gene range 3–6): WNK1.
- chr12:865,288–2,697,950, 32 genes, copy number 6 (within-gene range 4–6): AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B, CACNA1C, AC005342.1, CACNA1C-IT1, CACNA1C-IT2, AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1.
- chr12:5,948,877–8,597,640, 163 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:33,597,057–34,659,878, 16 genes, copy number 12–14 (within-gene range 4–14): AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP.
- chr14:36,054,197–38,728,481, 44 genes, copy number 29: ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1, AL357094.1, KRT8P1.
- chr20:87,250–23,030,785, 437 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:42,072,752–46,684,467, 145 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:48,624,252–54,070,594, 109 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
